Somatic mutation profile of tumor specimen BA2376D (aliquot aq-BA2376D) from BEATAML1.0 case 2513, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.0 years (22,636 days).
Specimen BA2376D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1cd98e2-7605-48da-a561-9fc3dc41c058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2609D (Solid Tissue Normal), aliquot aq-BA2609D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdf68ead-8836-424b-beec-e0476382bbbb

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICDL1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57492425; called by muse, mutect2, varscan2
- PEG3 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs762141634, COSV55631527, COSV55638935; called by muse, mutect2, varscan2
- CCNG2 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2
- IKZF1 | c.1422C>A p.H474Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAP3K6 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
